Somatic mutation profile of tumor specimen TCGA-EO-A1Y8-01A (aliquot TCGA-EO-A1Y8-01A-11D-A159-09) from TCGA case TCGA-EO-A1Y8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-EO-A1Y8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 977239fd-92e0-4293-bd3b-552c7733031d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A1Y8-10A (Blood Derived Normal), aliquot TCGA-EO-A1Y8-10A-01D-A159-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24ef533e-ceb7-42ce-b2a0-494329b4faa5

The open-access MAF lists 53 somatic variants for this specimen: 37 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 14, 3'UTR 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.1647T>A p.N549K | Missense Mutation (SNP) | VAF 71/150 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913476, COSV60638757, COSV60639738; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 38/79 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 9/17 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 26/28 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACBD3 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs537484387, COSV64729829; called by muse, mutect2, varscan2
- AMDHD1 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1375131926, COSV54116890; called by muse, mutect2, varscan2
- CDCA2 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV55339519; called by muse, mutect2, varscan2
- CDK16 | c.1324A>G p.K442E | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52091375; called by muse, mutect2, varscan2
- CIB2 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as rs1389425178, COSV51947801; called by muse, mutect2, varscan2
- CLASP2 | c.1129C>A p.L377I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV56278155; called by muse, mutect2, varscan2
- CNTN4 | c.2896G>A p.E966K | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV61869716; called by muse, mutect2, varscan2
- DENND5A | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 55/83 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV60232277; called by muse, mutect2, varscan2
- DYNC2LI1 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53182614; called by muse, mutect2, varscan2
- FER1L6 | c.3157G>A p.E1053K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1221283360, COSV67548768; called by muse, mutect2
- GYG1 | c.287C>G p.S96* | Nonsense Mutation (SNP) | VAF 40/104 reads (38%) | catalogued as COSV56049052; called by muse, mutect2, varscan2
- HFM1 | c.2215T>C p.S739P | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV54023529; called by muse, mutect2, varscan2
- INO80D | c.1495G>T p.D499Y | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68958404; called by muse, mutect2, varscan2
- IPO4 | c.3146C>A p.T1049K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV61015593, COSV61018127; called by muse, mutect2, varscan2
- JMJD1C | c.5354G>T p.S1785I | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV59513508; called by muse, mutect2, varscan2
- KCNJ4 | c.1315T>G p.Y439D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV57856463; called by muse, mutect2, varscan2
- KLHL40 | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV55133306; called by muse, mutect2, varscan2
- LDHC | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV55003631; called by muse, mutect2, varscan2
- MAEA | c.955C>T p.R319C (on ENST00000303400 / NM_001017405.3; = p.R278C on NM_005882.5) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.339); catalogued as rs567814674, COSV53261703; called by muse, mutect2
- MAGEC3 | c.185T>G p.V62G | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV53577491; called by muse, mutect2, varscan2
- OR5D13 | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.495); catalogued as COSV100687143, COSV62333035, COSV62335674; called by muse, mutect2, varscan2
- OR8J3 | c.492C>A p.F164L | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100040808, COSV56879723; called by muse, mutect2, varscan2
- ORAI2 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV62689321, COSV62689340; called by muse, mutect2, varscan2
- PIGN | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 65/102 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs867624020, COSV62948282; called by muse, mutect2, varscan2
- PRPF18 | c.895T>C p.S299P | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV60724820; called by muse, mutect2, varscan2
- RPGR | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58833194, COSV58840202; called by muse, mutect2, varscan2
- SETDB2 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752504406, COSV51643563, COSV99320613; called by muse, mutect2, varscan2
- SLC4A8 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs749210596, COSV60649120; called by muse, mutect2, varscan2
- SPX | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57020361; called by muse, mutect2, varscan2
- TMPRSS15 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs377566419, COSV53036456; called by muse, mutect2, varscan2
- TRNT1 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs761145683, COSV51639821, COSV99214034; called by muse, mutect2, varscan2
- TRPM3 | c.1838G>C p.G613A (on ENST00000357533 / NM_001366142.2; = p.G456A on NM_020952.6) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV62582059; called by muse, mutect2, varscan2
- ZNF529 | c.1337G>C p.G446A | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61899687; called by muse, mutect2, varscan2
- A2M | c.3024C>G p.L1008= | Silent (SNP) | VAF 44/105 reads (42%) | catalogued as COSV59384114; called by muse, mutect2, varscan2
- ANKRD30A | c.2640C>T p.F880= (on ENST00000611781; = p.F824= on NM_052997.2) | Silent (SNP) | VAF 244/524 reads (47%) | catalogued as rs562184589, COSV100654471, COSV64606439; called by muse, mutect2, varscan2
- ARHGEF15 | c.2517C>A p.P839= | Silent (SNP) | VAF 10/12 reads (83%) | catalogued as COSV62724637; called by muse, mutect2, varscan2
- AVIL | c.1326C>T p.I442= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV57680823; called by muse, mutect2, varscan2
- CTNND2 | c.2961C>T p.I987= | Silent (SNP) | VAF 24/212 reads (11%) | catalogued as rs1263209412, COSV58873008, COSV58892440; called by muse, mutect2, varscan2
- FSCB | c.1467C>T p.A489= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as rs748894618, COSV61217195; called by muse, mutect2, varscan2
- FYN | c.1227C>T p.F409= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs760579248, COSV57611180; called by muse, mutect2, varscan2
- GRIK4 | c.795C>A p.I265= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV70800801; called by muse, mutect2, varscan2
- IPCEF1 | c.543G>A p.Q181= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV54541705; called by muse, mutect2
- ITIH4 | c.864G>A p.R288= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs1233798849, COSV56572265; called by muse, mutect2, varscan2
- MED18 | c.315C>T p.C105= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs1341628366, COSV65790408; called by muse, mutect2, varscan2
- PRUNE2 | c.4575C>T p.A1525= | Silent (SNP) | VAF 37/57 reads (65%) | catalogued as rs766558013, COSV65038889; called by muse, mutect2, varscan2
- PSG6 | c.423A>G p.L141= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as COSV51831091; called by muse, mutect2, varscan2
- TTC39B | c.747C>G p.L249= | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as COSV52608303; called by muse, mutect2, varscan2
- MFRP | chr11:119344370 C>T | 5'Flank (SNP) | VAF 11/35 reads (31%) | catalogued as COSV64128044; called by muse, mutect2, varscan2
- NME6 | c.*2G>A | 3'UTR (SNP) | VAF 44/75 reads (59%) | catalogued as rs752476972, COSV100189439; called by muse, mutect2, varscan2
